Somatic mutation profile of tumor specimen TCGA-ET-A39P-01A (aliquot TCGA-ET-A39P-01A-21D-A19J-08) from TCGA case TCGA-ET-A39P, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 73.4 years (26,817 days).
Specimen TCGA-ET-A39P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05d1a448-db2b-43b7-b8b2-15e70ea7859b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39P-10A (Blood Derived Normal), aliquot TCGA-ET-A39P-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03799bfa-ec7e-4dbd-9c6e-09fc291dd454

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACTR3B | c.53A>T p.K18M | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99754160; called by muse, mutect2, varscan2
- ADAR | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1458064091, COSV52716652; called by muse, mutect2, varscan2
- CSMD3 | c.6391T>C p.Y2131H (on ENST00000297405 / NM_001363185.1; = p.Y2027H on NM_052900.3) | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52209521; called by muse, mutect2, varscan2
- DMRTB1 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV65113273; called by muse, mutect2, varscan2
- DYNC1H1 | c.5189C>A p.A1730E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64138088; called by muse, mutect2, varscan2
- EDEM3 | c.2384A>G p.D795G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1232235846, COSV58925267; called by muse, mutect2, varscan2
- FOXR2 | c.88T>A p.L30I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV59258802; called by muse, mutect2, varscan2
- IGHV1-46 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs1555524772; called by muse, mutect2, varscan2
- IL7R | c.800G>T p.R267M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57409428; called by muse, mutect2, varscan2
- KRTCAP3 | c.481-2A>C p.X161_splice | Splice Site (SNP) | VAF 56/138 reads (41%) | catalogued as COSV51994621; called by muse, mutect2, varscan2
- SLC35E3 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.17); catalogued as rs1026592785, COSV57496050; called by muse, mutect2, varscan2
- TRO | c.2579G>T p.S860I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1190499292, COSV51502723; called by muse, mutect2, varscan2
- TTLL3 | c.2422G>C p.E808Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV59614728; called by muse, mutect2, varscan2
- ZNF668 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1444233661, COSV56211398; called by muse, mutect2, varscan2
- ATP2B2 | c.1617C>G p.T539= (on ENST00000352432; = p.T505= on NM_001683.5) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV59498991; called by muse, mutect2, varscan2
- C1orf146 | c.459T>G p.A153= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV64860724; called by muse, mutect2, varscan2
- ITGA8 | c.1068A>G p.E356= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV65230297; called by muse, mutect2, varscan2
- OR10A7 | c.246T>A p.L82= | Silent (SNP) | VAF 91/220 reads (41%) | catalogued as COSV58278818; called by muse, mutect2, varscan2
- SLC35E3 | c.24G>T p.V8= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99971833; called by muse, mutect2, varscan2
